Somatic mutation profile of tumor specimen TCGA-CZ-5988-01A (aliquot TCGA-CZ-5988-01A-11D-1669-08) from TCGA case TCGA-CZ-5988, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 38.7 years (14,131 days).
Specimen TCGA-CZ-5988-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b5fbd56a-006e-4920-8440-862d7124e059.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CZ-5988-11A (Solid Tissue Normal), aliquot TCGA-CZ-5988-11A-01D-1669-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f04193c-60b8-46b4-ae1a-fe49dc0d2860

The open-access MAF lists 48 somatic variants for this specimen: 31 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 16, Frame Shift Del 3, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAR | c.926A>T p.N309I | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as COSV52718939; called by muse, mutect2, varscan2
- ARFGEF3 | c.3905C>T p.A1302V | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs759743211, COSV52465726; called by muse, mutect2
- ASB3 | c.489A>C p.K163N | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.724); catalogued as COSV55078484; called by muse, mutect2, varscan2
- ATF2 | c.1000C>G p.P334A | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs372839325, COSV99908360; called by muse, mutect2, varscan2
- ATG2A | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as rs1244193296, COSV65967971; called by muse, mutect2
- BCAR3 | c.2228A>G p.H743R | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53077618; called by muse, mutect2, varscan2
- CD33 | c.365G>T p.R122I | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as COSV51803585; called by muse, mutect2, varscan2
- CEP164 | c.2348C>T p.A783V | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.272); catalogued as COSV54044441; called by muse, mutect2, varscan2
- CHD9 | c.8546T>C p.I2849T (on ENST00000398510 / NM_001382353.1; = p.I2833T on NM_025134.7) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.432); catalogued as COSV54610026, COSV54614045; called by muse, mutect2, varscan2
- COL6A6 | c.3299C>G p.T1100R | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV62032636; called by muse, mutect2, varscan2
- FGD5 | c.1232C>T p.P411L | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as rs1490042655; called by muse, mutect2
- IZUMO1 | c.485C>A p.S162Y | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV55807035; called by muse, mutect2, varscan2
- MAST4 | c.2719A>T p.R907W (on ENST00000403625 / NM_001164664.2; = p.R718W on NM_015183.3) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55135418; called by muse, mutect2, varscan2
- MTMR8 | c.1708C>T p.L570F | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.243); catalogued as COSV66395477; called by muse, mutect2, varscan2
- NOL4L | c.1108A>G p.M370V | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.879); catalogued as COSV62889975; called by muse, mutect2, varscan2
- NOM1 | c.1492G>T p.D498Y | Missense Mutation (SNP) | VAF 49/149 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV51981559; called by muse, mutect2, varscan2
- OR2AG2 | c.400del p.T134Pfs*3 | Frame Shift Del (DEL) | VAF 18/74 reads (24%) | catalogued as COSV58454917; called by mutect2, pindel, varscan2
- OR6N1 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 38/168 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58648670; called by muse, mutect2, varscan2
- POLR2B | c.460A>G p.I154V | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.042); catalogued as COSV58901931; called by muse, mutect2, varscan2
- PON3 | c.167A>T p.D56V | Missense Mutation (SNP) | VAF 93/443 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.068); catalogued as COSV55700714; called by muse, mutect2, varscan2
- PPP1R3A | c.139G>T p.D47Y | Missense Mutation (SNP) | VAF 40/219 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); catalogued as COSV52889108, COSV99494653; called by muse, mutect2, varscan2
- PTPN21 | c.293A>G p.Y98C | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs935341465, COSV60850603; called by muse, mutect2, varscan2
- SLC26A5 | c.785T>C p.L262P | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV59704511; called by muse, mutect2, varscan2
- SMTNL2 | c.1230G>C p.K410N (on ENST00000389313 / NM_001114974.2; = p.K266N on NM_198501.3) | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.257); catalogued as COSV58809311; called by muse, mutect2, varscan2
- SON | c.3229C>A p.P1077T | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV51666199; called by muse, mutect2, varscan2
- SULT1C3 | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61254193; called by muse, mutect2, varscan2
- TEX15 | c.5996C>T p.A1999V (on ENST00000256246; = p.A2382V on NM_001350162.2) | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs867269469, COSV56350556; called by muse, varscan2
- CCDC54 | c.179_180dup p.D61Mfs*5 | Frame Shift Ins (INS) | VAF 28/151 reads (19%) | called by mutect2, pindel, varscan2
- CNNM3 | c.1377del p.V460Wfs*2 | Frame Shift Del (DEL) | VAF 43/235 reads (18%) | called by mutect2, pindel, varscan2
- KLHL2 | c.1680del p.E561Nfs*17 | Frame Shift Del (DEL) | VAF 42/152 reads (28%) | called by mutect2, pindel, varscan2
- TRAV7 | c.23T>C p.V8A | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADORA2B | c.204C>T p.S68= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV58482814; called by muse, mutect2, varscan2
- EXOSC9 | c.42A>G p.L14= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as COSV54667312; called by muse, mutect2, varscan2
- FBXO4 | c.867C>T p.F289= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV55853427; called by muse, mutect2, varscan2
- FFAR2 | c.807C>T p.D269= | Silent (SNP) | VAF 47/150 reads (31%) | catalogued as COSV55832928; called by muse, mutect2, varscan2
- HELZ2 | c.6702G>C p.L2234= (on ENST00000467148 / NM_001037335.2; = p.L1665= on NM_033405.3) | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV71296579; called by muse, mutect2
- NCAPG | c.1023C>G p.A341= | Silent (SNP) | VAF 43/141 reads (30%) | catalogued as COSV52271823; called by muse, mutect2, varscan2
- NR2F6 | c.894C>T p.D298= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV52244837; called by muse, mutect2, varscan2
- OR1I1 | c.231C>T p.T77= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as rs780565224, COSV52918627; called by muse, mutect2, varscan2
- OR2G2 | c.735C>T p.F245= | Silent (SNP) | VAF 32/97 reads (33%) | catalogued as COSV60741518; called by muse, mutect2, varscan2
- OR52J3 | c.438T>C p.I146= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as COSV66747475; called by muse, mutect2, varscan2
- PCSK5 | c.1542C>T p.I514= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as COSV65093528; called by muse, mutect2, varscan2
- SEMA6C | c.2055G>A p.P685= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs1166739430, COSV59005995; called by muse, mutect2, varscan2
- SLITRK5 | c.2181A>G p.P727= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV61524875; called by muse, mutect2, varscan2
- SPTBN1 | c.3948T>C p.H1316= | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as COSV61691613; called by muse, mutect2, varscan2
- SUSD2 | c.435G>T p.L145= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as COSV64204856; called by muse, mutect2, varscan2
- TTN | c.72450C>T p.A24150= (on ENST00000591111; = p.A16726= on NM_003319.4) | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as rs764657858, COSV60230778; called by muse, mutect2, varscan2
- MACF1 | c.15832-10184A>C | Intron (SNP) | VAF 70/264 reads (27%) | catalogued as COSV57134564; called by muse, mutect2, varscan2
